Somatic mutation profile of tumor specimen PCProject_0123_T2_WES (aliquot PCProject_0123_T2_WES_1) from CMI case PCProject_0123, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 45.5 years (16,613 days).
Specimen PCProject_0123_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e725f9d-abd0-4d72-816f-54fe69467f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0123_SALIVA_2 (DNA), aliquot PCProject_0123_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/696df3d6-9232-4b3c-a572-705bd4b218d6

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, 3'UTR 2, Frame Shift Del 1, RNA 1, Nonsense Mutation 1, Splice Site 1, 5'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WNT7A | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 67/804 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs879255548, COSV53198977; ClinVar: pathogenic; called by muse, mutect2
- ACTRT2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as rs977084051, COSV65759494; called by muse, mutect2
- ALOXE3 | c.2065C>G p.R689G | Missense Mutation (SNP) | VAF 113/792 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM160339; called by muse, mutect2, varscan2
- ARHGAP39 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs774423765, COSV99430471; called by muse, mutect2, varscan2
- ARSI | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs200523103; called by muse, mutect2
- CREB5 | c.1099C>T p.R367* (on ENST00000357727 / NM_182898.4; = p.R360* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 123/557 reads (22%) | catalogued as COSV63222931; called by muse, mutect2, varscan2
- DRC7 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 72/933 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs138457451; called by muse, mutect2
- F13B | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV66373617; called by muse, mutect2
- KRT34 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 76/922 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs776698603; called by muse, mutect2
- NFASC | c.1339C>T p.R447W (on ENST00000339876 / NM_001378329.1; = p.R458W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs774424825; called by muse, mutect2
- PPP2R5C | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.069); catalogued as rs898759735; called by muse, mutect2
- AOAH | c.127+1G>T p.X43_splice | Splice Site (SNP) | VAF 63/318 reads (20%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.3829C>A p.P1277T (on ENST00000236925 / NM_001297707.2; = p.P1266T on NM_203459.3) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2
- CTNND2 | c.3112G>C p.A1038P | Missense Mutation (SNP) | VAF 122/639 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FAT3 | c.600A>T p.K200N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GRM7 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- LARS2 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 86/569 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MED13L | c.6247T>C p.S2083P | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTHFSD | c.413T>C p.V138A (on ENST00000360900 / NM_001159377.2; = p.V137A on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR4K2 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRSS54 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 41/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PUM2 | c.2821del p.S941Pfs*8 | Frame Shift Del (DEL) | VAF 25/238 reads (11%) | called by mutect2, pindel, varscan2
- RAF1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RSF1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); called by muse, mutect2
- SPDYE3 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 208/1309 reads (16%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TMPRSS2 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ERP29 | c.246C>T p.S82= | Silent (SNP) | VAF 87/504 reads (17%) | catalogued as rs1190828909; called by muse, mutect2, varscan2
- HSPB3 | c.444G>C p.G148= | Silent (SNP) | VAF 53/666 reads (8%) | called by muse, mutect2
- ITIH6 | c.2781C>T p.L927= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, varscan2
- MAGEE1 | c.1920C>T p.Y640= | Silent (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- PANK1 | c.18T>A p.G6= | Silent (SNP) | VAF 150/860 reads (17%) | called by muse, mutect2, varscan2
- PRND | c.276C>T p.N92= | Silent (SNP) | VAF 118/1588 reads (7%) | catalogued as rs370883023; called by muse, mutect2
- SLC35G4 | c.261T>G p.L87= | Silent (SNP) | VAF 62/1026 reads (6%) | called by muse, mutect2
- AC244258.1 | n.506G>A | RNA (SNP) | VAF 19/159 reads (12%) | catalogued as rs750581888; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827310 C>A | 3'Flank (SNP) | VAF 80/320 reads (25%) | catalogued as rs772264951; called by muse, mutect2, varscan2
- ATP2B2 | c.*53C>T | 3'UTR (SNP) | VAF 56/882 reads (6%) | catalogued as rs1294453195, COSV100659925; called by muse, mutect2
- IMPACT | c.-59C>G | 5'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- PHKA2 | c.3337-16C>T | Intron (SNP) | VAF 142/392 reads (36%) | catalogued as COSV101177082; called by muse, mutect2, varscan2
- PITPNB | c.*99T>C | 3'UTR (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
